Gene-level copy-number profile of tumor specimen TCGA-DY-A1H8-01A from TCGA case TCGA-DY-A1H8, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 77.9 years (28,459 days).
Specimen TCGA-DY-A1H8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.7de63a7f-0c03-4096-aa04-e369207861ef.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DY-A1H8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/81cf03bc-9af1-415e-9d60-52ce9cdb68b7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 4,702; copy number 2: 46,773; copy number 3: 6,905; copy number 4: 73; copy number 5: 856; copy number 6: 139; copy number 7: 32; copy number 8: 3; copy number 9: 182; copy number 10: 61; copy number 11: 36; copy number 13: 3; copy number 15: 18; copy number 16: 31.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DY-A1H8-01A-21D-A151-01): tumor purity 0.89, ploidy 2.13, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:15,021,553–15,280,873, 3 genes: RNU6-1159P, RNU6-115P, RNA5SP475.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,361 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:168,695,468–172,468,831, 87 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr1:175,944,831–181,808,084, 100 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr1:181,962,889–188,536,465, 116 genes, copy number 5–10 (within-gene range 1–10) (broad region; genes not listed).
- chr1:188,869,474–199,080,975, 101 genes, copy number 7–16 (within-gene range 1–16) (broad region; genes not listed).
- chr1:202,891,116–209,266,758, 182 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr1:214,870,734–214,988,040, 3 genes, copy number 6: GAPDHP24, AC099563.1, AC099563.2.
- chr20:28,563,850–60,814,211, 772 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,648. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
